Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A83M, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A83M-01A (Primary Tumor).

[page 1 of 4]
MRN
Name
Encounter Number

Gender
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Final

Source of Specimen

- A. LEFT PELVIC LYMPH NODES-
- B. RIGHT PELVIC LYMPH NODES-
- C. PROSTATE, SEMINAL VESICLES AND VASA DEFERENTIA-

FINAL DIAGNOSIS:

- A. LEFT PELVIC LYMPH NODES-
TWO LYMPH NODES (0/2), NO TUMOR SEEN.
- B. RIGHT PELVIC LYMPH NODES-
TWO LYMPH NODES (0/2), NO TUMOR SEEN.
- C. PROSTATE, SEMINAL VESICLES AND VASA DEFERENTIA-
ADENOCARCINOMA OF PROSTATE.

TUMOR SITE: BILATERAL, MOSTLY IN PERIPHERAL ZONE.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 29 GRAMS. SIZE: 4.0 x 3.0 x 3.0 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 4 + 3 = 7/10.

TERTIARY PATTERN: IS NOT PRESENT.

SEVERITY IN EXTENT OF TUMOR: 5/5.

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): IS PRESENT, 1.0 CM IS SIZE.

C6CF *ICD-O-3*
Adenocarcinoma, acinar
path *8/40/13*
Adenocarcinoma NOS *8/40/13*
State Prostate NOS
C61.9
9/11/24/13

[page 2 of 4]
TREATMENT EFFECT ON CARCINOMA: N/A.

TNM STAGE: AT LEAST pT2c (SEE COMMENT), pN0, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: IS NOT SEEN.

PERINEURAL INVASION: IS PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

MARGIN STATUS:

POSITIVE INKED MARGINS: LEFT ANTERIOR PROSTATE (C11) AND
RIGHT POSTERIOR (C14), SEE COMMENT.

OTHER MARGINS ARE CLEAR.

COMMENT: THERE IS NO EXTRAPROSTATIC SOFT TISSUE IDENTIFIED AT
THE POSITIVE MARGINS. THE PERIPROSTATIC SOFT TISSUE IDENTIFIED
IN REMAINING SECTIONS, IS NOT INVOLVED BY TUMOR.

Signed Others

Frozen Section

A. RIGHT PELVIC LYMPH NODES, GROSS EXAM: 1.7 X 1 X 1 CM
FRAGMENT OF LOBULATED ADIPOSE TISSUE. NO LYMPH NODES PALPATED
OR SEEN. DEFERRED FOR PERMANENTS.

LEFT PELVIC LYMPH NODES, GROSS EXAM: 4.2 X 0.9 X 0.5 CM
ELONGATED FRAGMENT OF LOBULATED ADIPOSE TISSUE. NO LYMPH NODES
PALPATED OR SEEN. DEFERRED FOR PERMANENTS.

FS performed by

Case Clinical Information

PROSTATE CANCER

Gross Description

A. Received in formalin labeled with the patient's name and
"left pelvic lymph nodes" is a single elongated nodule with
attached fat and an attached suture with no definitive
orientation to the suture on the container or the requisition.
The specimen measures 4 x 1 x 0.3 cm thick. The suture is

[page 3 of 4]
removed. The entire specimen is bisected and submitted in A1.
B. Received in formalin labeled with the patient's name and "right pelvic lymph nodes" is a single elongated nodule of tan, fatty tissue measuring 3 x 1 x 0.3 cm in maximal thickness. The specimen is bisected and entirely submitted in B1.
C. Received in formalin labeled "prostate, seminal vesicles and vasa deferentia" is a radical prostatectomy specimen which includes a 29 gram prostate gland with attached seminal vesicles and vasa deferentia. The prostate gland measures 4 x 3 x 3 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 3 x 1 x 1 cm. The right vas measures 2 cm in length. The left seminal vesicle measures 2.8 x 1 x 1 cm. The left vas measures 2.5 cm in length. The inferior prostate is sectioned transversely, removed from the rest of the specimen and sectioned from anterior to posterior following the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no gross abnormalities. Representative sections submitted as follows: inferior prostate demonstrating apical margin submitted entirely anterior to posterior in C1-C7; bladder resection margin in C8-C10; complete section of mid gland anterior in C11, C12; posterior in C13, C14; complete section of upper third of gland, anterior in C15, C16; posterior in C17, C18; remainder of the posterior gland entirely submitted in C19-C21; right seminal vesicle and vas deferens in C22; and left seminal vesicle and vas deferens in C23.

Procedure

- A. AA ROUTINE H&E X1 BLOCK
H&E X1
- B. AA ROUTINE H&E X1 BLOCK
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.1
H&E X1 A RECUTS
- C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.4
H&E X1
- C. AA ROUTINE H&E X1 BLOCK.5
H&E X1

[page 4 of 4]
C. AA ROUTINE H&E X1 BLOCK.6
H&E X1
C. AA ROUTINE H&E X1 BLOCK.7
H&E X1
C. AA ROUTINE H&E X1 BLOCK.8
H&E X1
C. AA ROUTINE H&E X1 BLOCK.9
H&E X1
C. AA ROUTINE H&E X1 BLOCK.10
H&E X1
C. AA ROUTINE H&E X1 BLOCK.11
H&E X1 A RECUTS
C. AA ROUTINE H&E X1 BLOCK.12
H&E X1
C. AA ROUTINE H&E X1 BLOCK.13
H&E X1
C. AA ROUTINE H&E X1 BLOCK.14
H&E X1 A RECUTS
C. AA ROUTINE H&E X1 BLOCK.15
H&E X1
C. AA ROUTINE H&E X1 BLOCK.16
H&E X1
C. AA ROUTINE H&E X1 BLOCK.17
H&E X1
C. AA ROUTINE H&E X1 BLOCK.18
H&E X1 A RECUTS
C. AA ROUTINE H&E X1 BLOCK.19
H&E X1
C. AA ROUTINE H&E X1 BLOCK.20
H&E X1
C. AA ROUTINE H&E X1 BLOCK.21
H&E X1 A RECUTS
C. AA ROUTINE H&E X1 BLOCK.22
H&E X1
C. AA ROUTINE H&E X1 BLOCK.23
H&E X1

Source: NCI Genomic Data Commons file 0c523fc2-003a-4be5-89e7-65dd6ded5b8e (TCGA-J4-A83M.8AA3EBE4-49E8-4D0A-A3A4-B51E41B3AA4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).